TCGA case TCGA-HI-7168 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25d70934-01a5-45a2-9960-68d3058b6965

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,881 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 9.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Initial disease status: Recurrent Disease; Days to treatment start: 341 days; Days to treatment end: 1,923 days (5.3 years); Number of cycles: 13; Prescribed dose: 22.5; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 354 days; Days to treatment end: 400 days (1.1 years); Treatment dose: 6,800 cGy; Course number: 1; Number of fractions: 34; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 1,552 days (4.2 years); Days to treatment end: 2,014 days (5.5 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 2,511 days (6.9 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Biochemical Recurrence.

Follow-up (9 entries)
- Day 19 (initial diagnosis): Days to imaging: 19 days; Imaging type: MRI; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 19 (initial diagnosis): Days to imaging: 19 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Days to follow up: 308 days; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 308 days.
- Days to follow up: 1,523 days (4.2 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 1,523 days (4.2 years).
- Days to follow up: 2,391 days (6.5 years); Disease response: With Tumor.
- Day 2,505 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 2,505 days (6.9 years).
- Days to follow up: 3,323 days (9.1 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 2,315.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.3 ng/mL (day 2,289).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HI-7168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-HI-7168-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 58.
  Slide TCGA-HI-7168-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60.
- Sample TCGA-HI-7168-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HI-7168-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: No; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Biochemical recurrence indicator: Yes.
- Stage record, Psa: PSA most recent results: 0.3.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Lupron; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IM.
- Follow-up form 1: Treatment outcome first course: Stable Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Progression after hormone treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event site: Bone; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Progression after hormone treatment: Yes; Progression after hormone treatment type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,323 days; disease-specific survival: no event (censored), 3,323 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,505 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HI-7168-01A-11D-2112-01): tumor purity 0.57, ploidy 3.46, whole-genome doublings 1.
